Somatic mutation profile of tumor specimen TARGET-10-PASRCV-09A (aliquot TARGET-10-PASRCV-09A-01D) from TARGET case TARGET-10-PASRCV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,241 days).
Specimen TARGET-10-PASRCV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9b6fe44-1b5e-43ae-8594-457cdc1c3519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASRCV-10A (Blood Derived Normal), aliquot TARGET-10-PASRCV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44fc9210-2925-49f0-8a1d-90abbffb1ab2

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT6B | c.5836C>A p.R1946S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54755013; called by muse, mutect2
- SLC4A5 | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61030352; called by muse, mutect2, varscan2
- ADAMTS12 | c.3607G>T p.D1203Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADAMTS16 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2
- ITPRID1 | c.2515C>A p.H839N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); called by muse, mutect2
- MASP2 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RANBP9 | c.1549G>T p.V517L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2
- ROR1 | c.2271C>A p.S757R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- SLC45A3 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2
- SNX14 | c.868G>T p.D290Y (on ENST00000314673 / NM_001350535.1; = p.D246Y on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF514 | c.962G>T p.C321F | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCL24 | c.225C>T p.G75= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs200259580, COSV56116466; called by muse, mutect2, varscan2
- TARM1 | c.804G>T p.V268= (on ENST00000616041 / NM_001330650.1; = p.V260= on NM_001135686.3) | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- SH3YL1 | c.1+100G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
